Somatic mutation profile of tumor specimen TCGA-B1-A655-01A (aliquot TCGA-B1-A655-01A-11D-A31Z-10) from TCGA case TCGA-B1-A655, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 77.8 years (28,433 days).
Specimen TCGA-B1-A655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8dc7dfcc-6bf6-4b5f-be99-eb70578a2b3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-A655-10A (Blood Derived Normal), aliquot TCGA-B1-A655-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5b2fbd6-ae82-4846-88bf-0b3a20d16ea6

The open-access MAF lists 98 somatic variants for this specimen: 71 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 25, Frame Shift Del 13, Nonsense Mutation 3, In Frame Ins 1, Intron 1, RNA 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 27/113 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.2747G>T p.W916L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV64607388; called by muse, mutect2, varscan2
- ADAMTS6 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.539); catalogued as rs1300137174, COSV66865812; called by muse, mutect2, varscan2
- ALPK3 | c.2858A>T p.D953V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1393907055, COSV51941444; called by muse, mutect2, varscan2
- AMER3 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as rs1553491167, COSV58468551; called by muse, mutect2, varscan2
- ASB8 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV56660958; called by muse, mutect2, varscan2
- ATG13 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as COSV56322661; called by muse, mutect2
- ATP13A2 | c.2146C>A p.L716M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV58704525; called by muse, mutect2, varscan2
- BFAR | c.261C>T p.L87= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV55494785; called by muse, mutect2
- BRWD1 | c.641C>A p.S214* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as COSV58123950; called by muse, mutect2, varscan2
- CACNA1H | c.5830C>A p.H1944N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV52358928; called by muse, mutect2, varscan2
- CCDC171 | c.2000T>C p.L667P | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52655417; called by muse, mutect2, varscan2
- DDR2 | c.363T>G p.N121K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV63375056; called by muse, mutect2, varscan2
- DISP2 | c.2365C>G p.P789A | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51148449; called by muse, mutect2, varscan2
- DNAH5 | c.5864T>G p.I1955R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54257917; called by muse, mutect2, varscan2
- ENPP3 | c.2231A>C p.N744T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62957370; called by muse, mutect2, varscan2
- ERLIN1 | c.347C>G p.T116S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV64941523; called by muse, mutect2, varscan2
- FER1L5 | c.5395A>C p.K1799Q (on ENST00000623019; = p.K1763Q on NM_001293083.2) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs771739420, COSV53844513; called by muse, mutect2, varscan2
- GCK | c.1073G>C p.R358P | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.14); catalogued as COSV56269328; called by muse, mutect2, varscan2
- GUF1 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV55785384; called by muse, mutect2, varscan2
- H2BC11 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60363013; called by muse, mutect2, varscan2
- HEATR6 | c.3434C>A p.P1145Q | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51749674; called by muse, mutect2, varscan2
- ICAM1 | c.1475T>A p.I492K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV53427709; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1583A>C p.K528T | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56309070; called by muse, mutect2, varscan2
- INO80B | c.988T>A p.C330S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51972474; called by muse, mutect2, varscan2
- KCNK16 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64679740; called by muse, mutect2, varscan2
- LCOR | c.3943A>C p.N1315H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53719336; called by muse, mutect2, varscan2
- LONRF2 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as rs182810197, COSV66539537, COSV66539585; called by muse, mutect2
- LOXL2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66694013; called by muse, mutect2, varscan2
- LRMDA | c.400A>G p.R134G | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV65285476; called by muse, mutect2, varscan2
- MGA | c.3254G>C p.R1085T | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54964727; called by muse, mutect2, varscan2
- MRE11 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV100120183; called by muse, mutect2
- MYOM2 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV50735667, COSV50793656; called by mutect2, varscan2
- PCNX3 | c.4391A>C p.Y1464S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63141386; called by muse, mutect2, varscan2
- PCYT2 | c.492+2T>C p.X164_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV58712894; called by muse, mutect2, varscan2
- PKD2 | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM1413568, COSV52936798, COSV52941840; called by muse, mutect2, varscan2
- POM121C | c.869T>G p.L290R (on ENST00000607367; = p.L48R on NM_001099415.3) | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57549989; called by muse, mutect2, varscan2
- PPP4R3B | c.1397del p.F466Sfs*14 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as COSV55403453; called by mutect2, pindel, varscan2
- RASGRP1 | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60368097; called by muse, mutect2, varscan2
- RFPL3 | c.136T>A p.Y46N (on ENST00000249007 / NM_001098535.1; = p.Y17N on NM_006604.2) | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV50754414; called by muse, mutect2, varscan2
- RFPL3 | c.137A>T p.Y46F (on ENST00000249007 / NM_001098535.1; = p.Y17F on NM_006604.2) | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as COSV50754464; called by muse, mutect2, varscan2
- RHOB | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as COSV55357414; called by muse, mutect2, varscan2
- RPIA | c.786T>G p.F262L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52172209; called by muse, mutect2
- RPS8 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV63234634; called by muse, mutect2, varscan2
- SERPINA12 | c.539T>G p.F180C | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV57946699; called by muse, mutect2, varscan2
- SLC39A4 | c.764C>A p.P255H (on ENST00000301305 / NM_001374839.1; = p.P230H on NM_017767.3) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV52781958; called by muse, mutect2, varscan2
- SMC6 | c.1534A>T p.I512F | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV61179089; called by muse, mutect2, varscan2
- SNX9 | c.1464C>A p.F488L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.303); catalogued as COSV67584274, COSV67586322; called by muse, mutect2, varscan2
- SSTR3 | c.1249T>C p.Y417H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV60730583; called by muse, mutect2
- TCEAL4 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV65464192; called by muse, mutect2, varscan2
- TLN1 | c.7352A>C p.E2451A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV59212765; called by muse, mutect2, varscan2
- TTC39B | c.1105G>C p.G369R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52618005; called by muse, mutect2
- TTN | c.26287G>A p.D8763N (on ENST00000591111; = p.D7836N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | PolyPhen benign (0); catalogued as rs1405635875, COSV59938959; called by muse, mutect2, varscan2
- UBTD2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV67143875, COSV67143997, COSV67144172; called by muse, mutect2, varscan2
- XIRP2 | c.9832C>T p.H3278Y (on ENST00000628543; = p.H3453Y on NM_152381.6) | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV54740377; called by muse, mutect2, varscan2
- ZKSCAN2 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV60159216; called by muse, mutect2, varscan2
- ZNF175 | c.1714T>C p.S572P | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV51799019; called by muse, mutect2, varscan2
- ARHGAP5 | c.773del p.Y258Ffs*26 | Frame Shift Del (DEL) | VAF 76/181 reads (42%) | called by mutect2, pindel, varscan2
- CACNA1A | c.1865del p.F622Sfs*37 | Frame Shift Del (DEL) | VAF 38/130 reads (29%) | called by mutect2, pindel, varscan2
- CEP152 | c.1323del p.S442Qfs*21 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- CSF3R | c.440_442dup p.G147_P148insR | In Frame Ins (INS) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- CYP4X1 | c.170del p.H57Pfs*47 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- EIF2AK1 | c.1275dup p.L426Ifs*10 | Frame Shift Ins (INS) | VAF 9/49 reads (18%) | called by mutect2, varscan2
- GALNT6 | c.918del p.F306Lfs*22 | Frame Shift Del (DEL) | VAF 31/111 reads (28%) | called by mutect2, pindel, varscan2
- NFATC2 | c.1944_1945del p.H649Yfs*39 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- NPR2 | c.1337del p.P446Hfs*31 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- POU6F2 | c.2010del p.K670Nfs*14 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- RGS6 | c.607del p.H203Tfs*8 | Frame Shift Del (DEL) | VAF 64/160 reads (40%) | called by mutect2, pindel, varscan2
- SCIN | c.1454del p.L485Cfs*51 (on ENST00000297029 / NM_001112706.3; = p.L238Cfs*51 on NM_033128.3) | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- SLC25A12 | c.407_422del p.H136Rfs*36 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- STARD3 | c.452_459del p.G151Afs*17 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- AFAP1 | c.1029A>G p.S343= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV61799587; called by muse, mutect2, varscan2
- AMACR | c.660T>C p.Y220= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV59463113; called by muse, mutect2, varscan2
- AMPD1 | c.1095T>C p.Y365= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV62419611; called by muse, mutect2, varscan2
- BRCA1 | c.5313C>T p.P1771= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs1131692076, COSV58801909; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK1 | c.1842T>A p.T614= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV54764274; called by muse, mutect2, varscan2
- ERCC6L | c.924C>A p.A308= | Silent (SNP) | VAF 6/147 reads (4%) | catalogued as COSV57822691; called by muse, mutect2
- EXOSC4 | c.258C>T p.R86= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV60156341; called by muse, mutect2, varscan2
- FASTKD2 | c.1926T>C p.S642= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV52700593; called by muse, mutect2, varscan2
- FSCN2 | c.822G>A p.R274= | Silent (SNP) | VAF 67/114 reads (59%) | catalogued as COSV58369732; called by muse, mutect2, varscan2
- GJD4 | c.435C>A p.I145= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV58703601; called by muse, mutect2, varscan2
- GPR89A | c.1302T>C p.A434= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1409997654, COSV100572560; called by mutect2, varscan2
- HELZ | c.1782A>G p.Q594= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs747499913, COSV62379140; called by muse, mutect2
- HIPK3 | c.3417T>C p.S1139= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV57566504; called by muse, mutect2, varscan2
- KCNG2 | c.747G>A p.A249= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs140841838; called by muse, mutect2, varscan2
- MED27 | c.450T>C p.A150= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV52607435; called by muse, mutect2, varscan2
- MME | c.912A>G p.T304= | Silent (SNP) | VAF 101/301 reads (34%) | catalogued as COSV64711504; called by muse, mutect2, varscan2
- MYT1L | c.3225A>G p.E1075= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV67705262; called by muse, mutect2, varscan2
- NPR2 | c.381T>C p.S127= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1420791224, COSV61315141; called by muse, mutect2, varscan2
- OR1N2 | c.465C>T p.T155= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV65461368; called by muse, mutect2, varscan2
- PCDHGA5 | c.1743C>T p.S581= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs766163319, COSV54051774; called by muse, mutect2, varscan2
- PRSS35 | c.453C>T p.S151= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV63801360; called by muse, mutect2, varscan2
- RAP1GAP | c.888C>G p.V296= | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as COSV51580197; called by muse, mutect2, varscan2
- RGS14 | c.1614C>T p.P538= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV68772136; called by muse, mutect2, varscan2
- TRPM4 | c.900C>T p.L300= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs1247591134, COSV53262467; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1485T>C p.Y495= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV56274971; called by muse, mutect2, varscan2
- AC244258.1 | n.580G>C | RNA (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.747+1270A>T | Intron (SNP) | VAF 60/209 reads (29%) | catalogued as COSV99791413; called by muse, mutect2, varscan2
